Surgical pathology report (de-identified scan), TCGA case TCGA-44-7661, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-44-7661-01A (Primary Tumor).

[page 1 of 2]
[REDACTED]

Phon [REDACTED]

Final Surgical Pathology Report

Procedure: [REDACTED]

Diagnosis

A. Right lower lobe of lung, lobectomy: Right lower lobe of lung with subpleural poorly differentiated adenocarcinoma. Vascular invasion present. Bronchial and vascular margins of resection negative for tumor.

B. Level II, excision: Lymph node with anthracosis, negative for metastatic disease.

C. Level VII, excision: Lymph node with anthracosis, negative for metastatic disease.

D. R4, excision: Lymph nodes negative for metastatic disease

Microscopic Description:

This right lower lobe of lung contains a subpleural, poorly differentiated adenocarcinoma. Stain for TTF1 is strongly positive, supporting a lung primary. The tumor measures 3.5 cm in maximum dimension. Arterial invasion is noted. Please see the template below:

Histologic type: Adenocarcinoma

Histologic grade: Poorly differentiated

Primary tumor (pT): pT2a

Margins of resection: Negative

Direct extension of tumor: Negative

Venous (large vessel) invasion: Negative

Arterial (large vessel) invasion: Positive

Lymphatic (small vessel) invasion: Negative

Regional lymph nodes (pN): As per parts B. through D., all lymph nodes are negative for metastatic disease, pN0

Distant metastasis (pM): Cannot be assessed

Other findings: None

B. through D. microscopic examination performed

Specimen

A. Right lower lobe

B. Level II

C. Level VII

D. R4

Clinical Information

Lung cancer, endometrial cancer

Gross Description

A. The specimen is received fresh labeled "right lower lobe". It consists of the right lower lobe of lung weighing 176 g and measuring 16 x 11 x 3.7 cm. There is a 5.5 cm staple line near the hilum. Also in the hilar area there is a stapled bronchial stump which measures 6 mm in diameter when removing staples. A stapled vessel is also noted in the hilum measuring 7 mm in diameter. These margins appear unremarkable. The pleural surface is smooth and mostly pink and glistening with minimal anthracotic pigmentation. In the superior

[page 2 of 2]
anterior portion, however, there is marked puckering and retraction of the pleura. This area is painted black. On section it corresponds to a superficial, fleshy tan dull tumor mass measuring 3.5 x 2.1 x 2.5 cm.

A touch preparation is made and a sample is taken for Tissue Procurement. Remaining pulmonary parenchyma is soft pink and spongy. Upon exploring the major vessels and bronchi, no lesions are found. Rep. sections are submitted following fixation

Blood account: 1-bronchial and vascular margins esection ; 2 through 5-tumor; 6 through 7-noninvolved lung.

B. The specimen is received unfixed labeled "level II". It consists of a single glistening soft reddish black nodule measuring 0.7 cm in greatest dimension. It is bisected,

C. Received fresh labeled "level VII" is a 1.6 x 1.2 x 0.5 cm soft tan-red-gray tissue. The specimen is quadrasected and entirely submitted in one block.

D. Received fresh labeled "R4" is a 1.5 x 1.2 x 0.5 cm portion of soft lobulated gold and yellow adipose tissue with interspersed tan grey discoloration. The specimen is quadrasected and entirely submitted in block.

Source: NCI Genomic Data Commons file e13b4ef4-e804-48a7-8bd8-5c4703eb9ac8 (TCGA-44-7661.C21444E4-547B-4114-91C5-9852418E3E6B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).